Somatic mutation profile of tumor specimen TCGA-OR-A5JI-01A (aliquot TCGA-OR-A5JI-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JI, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 22.4 years (8,177 days).
Specimen TCGA-OR-A5JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86411c58-6afd-4c97-9aad-48aba8280c8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JI-10A (Blood Derived Normal), aliquot TCGA-OR-A5JI-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f357d0c-e22e-40c5-af20-c6776a0dfe88

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 9, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRTC3 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.895); catalogued as rs760877758; called by muse, mutect2, varscan2
- PTCHD4 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs191919500, COSV100260253; called by muse, mutect2, varscan2
- SIPA1L3 | c.5335A>G p.K1779E | Missense Mutation (SNP) | VAF 53/431 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as rs762358843; called by muse, varscan2
- SSX1 | c.331A>T p.I111F | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs781841275; called by mutect2, varscan2
- ZNF131 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as rs894336230; called by muse, mutect2, varscan2
- CDH4 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EXPH5 | c.3396del p.S1133Qfs*11 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- FAM171A1 | c.1126C>G p.P376A | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OPTN | c.312T>A p.N104K | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PKD2 | c.2882A>G p.N961S | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
